Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PS, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PS-01A (Primary Tumor).

[page 1 of 3]
HIIPA Discrepancy		☒
		fw 8/31/11

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

Papillary thyroid cancer.

Specimens Submitted:

- 1: Right para-tracheal tissue; biopsy
- 2: Right superior mediastinal tissue; biopsy
- 3: Thyroid, total thyroidectomy
- 4: Delphian lymph node; biopsy

DIAGNOSIS:

1. Right para-tracheal tissue; biopsy:
- Benign fibroadipose tissue.

2. Right superior mediastinal tissue; biopsy:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma consisting of a few psammoma bodies.

Number of lymph nodes examined: 1

Number of lymph nodes with metastatic disease: 1

Size of the largest lymph node involved by tumor: 0.2cm.

Extranodal extension is not identified

Comment: The psammoma bodies diagnostic of carcinoma were not present on the frozen section slide.

3. Thyroid, total thyroidectomy:

Tumor Type:

Multicentric papillary carcinoma, classical, tall and microcarcinoma variants.

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Left lobe

Right lobe

Isthmus

Tumor Size:

Greatest diameter is 1.1 cm.

for the classical type, tall cell (0.3 cm), microcarcinoma (0.25 and 0.35 cm)

Tumor Encapsulation:

1CD-0-3
carcinoma, papillary thyroid 8260/3
Site: thyroid, NOS C73.9
fw 8/31/11

[page 2 of 3]
The classical type is encapsulated, the other foci are unencapsulated

Capsular Invasion:

Extensive invasion
of tumor capsule by the classical type.

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Very focal extra-thyroid extension into adipose tissue by the isthmic microcarcinoma

Surgical Margins:

Free of tumor

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

One intrathyroidal parathyroid involved by carcinoma

Lymph Nodes:

One benign lymph node (0/1)

4. Delphian lymph node; biopsy:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 2

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation labeled "Right para-tracheal tissue", and consists of three fragments of yellow/pink soft tissue measuring 1.0 x 0.6 x 0.3 cm in aggregate. The specimen is entirely submitted for frozen section diagnosis.

Summary sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section consultation labeled "Right superior mediastinal tissue", and consists of fatty yellow soft tissue measuring 1.0 x 1.0 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis.

Summary sections:

FSC - frozen section control

3) The specimen is received fresh, labeled "total thyroidectomy stitch marks right lobe of thyroid" and consists of a thyroid weighing 10.05 g. The right lobe measures 4.0 x 2.2 x 1.1 cm, the left lobe measures 3.8 x 2.5 x 0.8 cm and the isthmus measures 1.0 x 0.8

[page 3 of 3]
x 0.3 cm. There is a 2.5 x 0.8 x 0.5 cm portion of skeletal muscle attached to the right lower lobe. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.1 x 0.8 x 0.7 cm white solid nodule in the right lower lobe (N1), and a 0.3 cm white solid nodule in left mid lobe (N2). The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N1 - nodule in the right lobe

N2 - nodule in the left lobe

RL - right lobe

LL - left lobe

IS - isthmus and skeletal muscle

4) The specimen is received in formalin, labeled "Delphian lymph node" and consists of single fatty lymph node measuring 0.5 x 0.4 x 0.3 cm. Entirely submitted.

Summary of sections:

LN - lymph node

Summary of Sections:

Part 1: Right para-tracheal tissue; biopsy

Block	Sect. Site	PCs
1	FSC	3

Part 2: Right superior mediastinal tissue; biopsy

Block	Sect. Site	PCs
1	FSC	1

Part 3: Thyroid, total thyroidectomy

Block	Sect. Site	PCs
1	IS	4
2	LL	4
2	N1	3
1	N2	2
2	RL	4

Part 4: Delphian lymph node; biopsy

Block	Sect. Site	PCs
1	LN	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Right para-tracheal tissue (fs): Benign
Permanent Diagnosis: Same
2. Frozen Section Diagnosis: Right superior mediastinal tissue (fs): Benign
Permanent Diagnosis: See final

Source: NCI Genomic Data Commons file 764a2348-88e6-4c3b-82d6-e01b02cd020c (TCGA-DJ-A2PS.B1F7E6CD-E09F-4E83-AA24-778687FDA264.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).